TCGA case TCGA-VQ-A8P2 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Stomach; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a0d35a25-3500-46f3-874f-1a0820200473

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 68.8 years (25,129 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,160 days (3.2 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 16.
   Treatment given: Treatment type: Chemotherapy; Days to treatment end: 107 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment end: 107 days; Treatment outcome: Complete Response; Number of fractions: 25.

Follow-up (3 entries)
- Days to follow up: 680 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 848 days (2.3 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,160.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VQ-A8P2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 160 mg.
  Slide TCGA-VQ-A8P2-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VQ-A8P2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VQ-A8P2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Mucinous Type; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Tumor sample procurement country: Sao Paulo; Cancer procurement city: Barretos; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical treatment ongoing indicator: No.
- Radiation treatment: Radiation therapy ongoing indicator: No.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,160 days; disease-specific survival: no event (censored), 1,160 days; disease-free interval: no event (censored), 1,160 days; progression-free interval: no event (censored), 1,160 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VQ-A8P2-01A-11D-A363-01): tumor purity 0.84, ploidy 2.05, whole-genome doublings 0.
